Somatic mutation profile of tumor specimen C3L-05338-54 (aliquot CPT0303680002) from CPTAC case C3L-05338, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.0 years (16,793 days).
Specimen C3L-05338-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c33828c5-e703-426e-8b07-99cde260923f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05338-51 (Buccal Cell Normal), aliquot CPT0303760001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62c9fd98-83e1-4b97-b578-3569198aa707

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- FABP6 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs200869631; called by muse, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- TECTA | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs876657587, COSV50700879; called by muse, mutect2, varscan2
- FAM171A1 | c.377T>A p.M126K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR52I1 | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- RTN4RL2 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- GRIK5 | c.1281C>T p.Y427= | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as rs779664291, COSV53484216; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9817G>A | Intron (SNP) | VAF 58/132 reads (44%) | catalogued as COSV101595574; called by muse, mutect2
